Gene-level copy-number profile of tumor specimen ALCH-AE0S-TTP1-A from ALCHEMIST case ALCH-AE0S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.7 years (26,184 days).
Specimen ALCH-AE0S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9699a71d-25f9-425b-be9f-6f4e83db3115.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,266 have no estimate.
https://portal.gdc.cancer.gov/files/e00776bd-90d3-41bb-a4f4-e4bbcdd10290

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 4,148; copy number 2: 17,932; copy number 3: 22,453; copy number 4: 8,248; copy number 5: 2,770; copy number 6: 1,449; copy number 7: 375; copy number 8: 194; copy number 9: 68; copy number 10: 39; copy number 11: 91; copy number 12: 20; copy number 13: 8; copy number 14: 36; copy number 15: 11; copy number 16: 46; copy number 17: 292; copy number 18: 2; copy number 19: 5; copy number 21: 76; copy number 51: 7; copy number 57: 11; copy number 69: 3; copy number 70: 4; copy number 98: 62.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:71,827,177–71,827,471, 1 gene: RN7SL271P.
- chr5:54,956,235–54,957,846, 1 gene: AC112198.2.
- chr5:158,485,190–158,588,546, 1 gene (within-gene range 0–1): AC091939.1.
- chr19:1,107,637–1,174,268, 1 gene: SBNO2.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,346 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,522,299–67,661,013, 5 genes, copy number 7: LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9.
- chr1:68,045,886–68,051,631, 2 genes, copy number 7 (within-gene range 5–7): DIRAS3, ARL5AP3.
- chr2:109,792,758–110,010,783, 9 genes, copy number 7–18: RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5, GPAA1P1, ZBTB45P1, LINC01123, AC013268.3.
- chr3:167,956,311–191,641,237, 409 genes, copy number 9–19 (within-gene range 9–21) (broad region; genes not listed).
- chr5:10,337,277–10,343,131, 2 genes, copy number 9: Y_RNA, AC012640.5.
- chr5:24,487,100–24,644,978, 3 genes, copy number 7: CDH10, AC091885.2, AC091885.1.
- chr5:32,103,445–32,175,272, 4 genes, copy number 7 (within-gene range 6–7): AC025178.1, GOLPH3, Y_RNA, AC025181.2.
- chr7:16,599,779–16,888,885, 10 genes, copy number 7–14: ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:63,843,314–65,554,744, 87 genes, copy number 7–11 (broad region; genes not listed).
- chr7:65,960,684–66,165,011, 8 genes, copy number 7: GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3.
- chr8:53,966,552–54,102,017, 5 genes, copy number 8: TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5.
- chr8:73,590,574–73,878,854, 4 genes, copy number 7 (within-gene range 6–7): AC100784.1, VENTXP6, AC027018.1, AC022826.2.
- chr8:75,120,409–76,407,138, 9 genes, copy number 7–8 (within-gene range 6–8): CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109.
- chr8:77,399,072–78,956,082, 12 genes, copy number 7: AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:79,891,553–80,568,506, 23 genes, copy number 7–9: AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2.
- chr8:81,521,618–84,164,564, 29 genes, copy number 7–8 (within-gene range 6–8): AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1.
- chr8:86,342,547–86,561,498, 5 genes, copy number 7–8 (within-gene range 6–8): WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3.
- chr8:94,641,074–94,793,836, 7 genes, copy number 7: ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1.
- chr10:14,061–1,737,525, 29 genes, copy number 8–9: AC215217.1, AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr10:3,065,424–3,258,897, 7 genes, copy number 7: AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.1, LINC02668.
- chr10:5,393,101–5,666,595, 10 genes, copy number 7: TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, LASTR, AL365356.2, RN7SL445P, ASB13.
- chr10:11,920,022–12,123,221, 4 genes, copy number 7–8: UPF2, RNU6-1095P, DHTKD1, RNU6-88P.
- chr10:21,865,335–21,933,438, 2 genes, copy number 7: AL359697.1, RN7SKP37.
- chr10:26,931,206–27,350,290, 17 genes, copy number 7: FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP.
- chr10:34,926,775–34,943,075, 2 genes, copy number 7: RNU6-847P, RNU6-193P.
- chr10:35,008,551–35,127,020, 3 genes, copy number 7 (within-gene range 6–7): CUL2, MIR3611, AL392046.1.
- chr10:36,521,721–36,626,138, 2 genes, copy number 7: NAMPTP1, Y_RNA.
- chr11:89,968,502–90,073,055, 10 genes, copy number 8: TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5.
- chr11:100,336,856–100,687,955, 4 genes, copy number 7 (within-gene range 6–7): RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1.
- chr11:118,531,041–118,572,970, 2 genes, copy number 8 (within-gene range 5–8): TMEM25, IFT46.
- chr13:18,467,172–19,865,048, 57 genes, copy number 7: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr13:110,305,812–114,337,626, 95 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr15:28,332,237–28,358,080, 3 genes, copy number 14: HERC2P1, AC091304.4, AC091304.1.
- chr15:83,012,661–83,090,782, 6 genes, copy number 7 (within-gene range 5–7): AC024270.3, BTBD1, AC022558.3, AC022558.1, AC024270.1, FABP5P8.
- chr15:101,922,042–101,938,470, 3 genes, copy number 10: OR4F4, OR4G2P, OR4G6P.
- chr16:10,944,564–11,976,643, 40 genes, copy number 8–10: CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr19:18,990,888–19,138,513, 4 genes, copy number 7 (within-gene range 6–7): SUGP2, ARMC6, SLC25A42, TMEM161A.
- chr19:19,276,018–19,754,986, 23 genes, copy number 7: SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5.
- chr19:37,817,359–40,950,660, 167 genes, copy number 7–98 (broad region; genes not listed).
- chr22:19,330,698–22,421,310, 206 genes, copy number 7–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
